Somatic mutation profile of tumor specimen TCGA-AJ-A6NU-01A (aliquot TCGA-AJ-A6NU-01A-11D-A34Q-09) from TCGA case TCGA-AJ-A6NU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 64.3 years (23,498 days).
Specimen TCGA-AJ-A6NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ae8893d-51b4-4230-86a7-f3aa5cce3b34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A6NU-10A (Blood Derived Normal), aliquot TCGA-AJ-A6NU-10A-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dcfddca-c7b2-4da5-a956-9e1e527a36a5

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 26, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.1290G>A p.W430* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100583967, COSV100584609; called by muse, mutect2, varscan2
- CES1 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV100828672; called by muse, mutect2
- CPNE9 | c.1616C>A p.P539Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV99808246; called by muse, mutect2, varscan2
- DOK1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51211765; called by muse, mutect2, varscan2
- FAM153A | c.330C>T p.N110= | Splice Region (SNP) | VAF 36/104 reads (35%) | catalogued as rs142185775; called by muse, mutect2, varscan2
- FKBP15 | c.3406A>T p.K1136* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99438821; called by muse, mutect2, varscan2
- GRB7 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100485489; called by muse, mutect2, varscan2
- IGSF9B | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs1470628751, COSV100317581; called by muse, mutect2, varscan2
- ILF3 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV99139700; called by muse, mutect2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- KRT18 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV101184014; called by muse, mutect2, varscan2
- LPA | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs202216263, COSV100306948; called by muse, mutect2, varscan2
- NID1 | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200467845, COSV51614828; called by muse, mutect2, varscan2
- NLRC3 | c.3115G>A p.G1039R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072783; called by muse, mutect2, varscan2
- NTN4 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs375475179, COSV59217355; called by muse, mutect2, varscan2
- OR2T27 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs757391223, COSV100788324, COSV61281501, COSV61283032; called by mutect2, varscan2
- PCDHA3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.223); catalogued as COSV100973837; called by muse, mutect2, varscan2
- PCDHA6 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100972265, COSV100972416; called by muse, mutect2
- PDZD4 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99381315; called by muse, mutect2, varscan2
- PIK3CD | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100740030, COSV100740149; called by muse, mutect2, varscan2
- PLXNB2 | c.4033C>T p.R1345C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775464863, COSV63780989; called by muse, mutect2, varscan2
- PLXNB2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs531070913, COSV63783054; called by muse, mutect2, varscan2
- RAB39B | c.602C>A p.S201* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV101034971; called by muse, mutect2, varscan2
- RAB39B | c.601T>A p.S201T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as COSV101034973; called by muse, mutect2, varscan2
- SMC1A | c.2154C>A p.D718E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.782); catalogued as COSV100447369; called by muse, mutect2, varscan2
- SPICE1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV99871345; called by muse, mutect2, varscan2
- SPO11 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs760369826, COSV100625708; called by muse, mutect2, varscan2
- TP53 | c.522del p.R174Sfs*73 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV52773028, COSV52839726, COSV53424551; called by mutect2, pindel, varscan2
- TUBA1C | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs551680115, COSV99988784; called by muse, mutect2, varscan2
- WASHC2C | c.3619G>A p.D1207N (on ENST00000336378; = p.D1186N on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1248398781, COSV60489933; called by muse, mutect2, varscan2
- KCNB2 | c.1466C>A p.P489Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T12 | c.913del p.T305Rfs*3 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- TMTC4 | c.570del p.A191Hfs*19 (on ENST00000376234 / NM_001350577.2; = p.A210Hfs*19 on NM_032813.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- CLU | c.156G>T p.G52= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100324296; called by muse, mutect2, varscan2
- IFT140 | c.3780G>A p.R1260= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100794315; called by muse, mutect2, varscan2
- IPO5 | c.1203A>C p.V401= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99847059, COSV99847286; called by muse, varscan2
- MOB1A | c.111A>T p.G37= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101247263; called by muse, mutect2, varscan2
- MSLN | c.1386C>G p.P462= (on ENST00000382862 / NM_013404.4; = p.P454= on NM_005823.6) | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV99558286; called by muse, mutect2, varscan2
- MTMR8 | c.1602A>G p.L534= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100878440; called by muse, mutect2, varscan2
- OCIAD1 | c.30G>A p.P10= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs1303396035, COSV99971149; called by muse, mutect2, varscan2
- PCDHB2 | c.1383C>T p.F461= | Silent (SNP) | VAF 46/285 reads (16%) | catalogued as rs375371663, COSV50575110; called by muse, mutect2, varscan2
- SMC2 | c.741A>T p.V247= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99658941; called by muse, mutect2, varscan2
- SYNE1 | c.18630C>G p.P6210= (on ENST00000367255 / NM_182961.4; = p.P6139= on NM_033071.3) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99563462; called by muse, mutect2, varscan2
- TRIO | c.5727C>T p.L1909= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs200594729, COSV100710340; called by muse, mutect2, varscan2
- UPF1 | c.2772C>T p.F924= (on ENST00000599848 / NM_001297549.2; = p.F913= on NM_002911.4) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV99438745, COSV99439563; called by muse, mutect2, varscan2
